Somatic mutation profile of tumor specimen 0DH292 from CCDI case PBBUBZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,413 days).
Specimen 0DH292: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b92bf94d-039a-4e10-abf6-bed14e405143.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH27G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ac79cde-ff30-4350-804d-a475804ad4b0

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 3, Intron 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 54/956 reads (6%) | catalogued as rs869025366, CM010160, COSV65807665; ClinVar: pathogenic; called by muse, mutect2
- CCM2 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 38/1510 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs1402559290, COSV51851680; called by muse, mutect2
- HTR1B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 56/836 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.129); catalogued as rs780026953, COSV64051042; called by muse, mutect2
- THRA | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 78/958 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1339532915; called by muse, mutect2
- ZNF572 | c.1187G>T p.S396I | Missense Mutation (SNP) | VAF 257/528 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1218149596; called by muse, mutect2, varscan2
- AC127029.3 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 403/1722 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 44/1166 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 38/858 reads (4%) | called by muse, mutect2
- HRH2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 28/862 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.14); called by muse, mutect2
- NRAP | c.1843G>C p.V615L (on ENST00000359988 / NM_001322945.2; = p.V580L on NM_006175.4) | Missense Mutation (SNP) | VAF 25/397 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.115); called by muse, mutect2
- RAB11FIP4 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 21/520 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); called by muse, mutect2
- SLC2A1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 54/956 reads (6%) | called by muse, mutect2
- STAG3 | c.822_828del p.Q274Hfs*25 | Frame Shift Del (DEL) | VAF 292/796 reads (37%) | called by mutect2, varscan2
- TACC2 | c.1589C>A p.A530E | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); called by muse, mutect2
- TBX10 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 66/1076 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 34/824 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 50/854 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- NHSL1 | c.1209G>A p.A403= | Silent (SNP) | VAF 48/825 reads (6%) | catalogued as rs200271083; called by muse, mutect2
- PCDHGA3 | c.1677G>A p.A559= | Silent (SNP) | VAF 340/968 reads (35%) | catalogued as COSV53958892; called by muse, mutect2, varscan2
- PCDHGB4 | c.1734C>T p.H578= | Silent (SNP) | VAF 45/774 reads (6%) | catalogued as rs1224398489, COSV53955612; called by muse, mutect2
- RASAL2 | c.2712C>T p.S904= | Silent (SNP) | VAF 283/600 reads (47%) | catalogued as rs371594678; called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 34/818 reads (4%) | catalogued as rs1267156464; called by muse, mutect2
- DDX19A | c.605-59G>T | Intron (SNP) | VAF 52/628 reads (8%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 28/492 reads (6%) | called by muse, mutect2
